BEATAML1.0 case 2038 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/6340041f-c75b-4e59-bf7a-cd43f8fba575

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myelomonocytic leukemia: ICD-O-3 morphology code: 9867/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 24.3 years (8,865 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (1 sample)
- Sample BA2887R: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
